Somatic mutation profile of tumor specimen C3L-01681-01 (aliquot CPT0110740008) from CPTAC case C3L-01681, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 76.1 years (27,785 days).
Specimen C3L-01681-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f150b912-b5a8-4c1f-811a-5e0b44807547.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01681-31 (Blood Derived Normal), aliquot CPT0112350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e70c62d-0aef-4540-9306-93f64b776990

The open-access MAF lists 114 somatic variants for this specimen: 81 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 20, 3'UTR 6, Frame Shift Del 6, Nonsense Mutation 4, Splice Site 3, 5'UTR 3, Intron 2, Frame Shift Ins 2, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 147/400 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs5030826, CM941362, CM941363, CM941364, COSV56543026, COSV56543035, COSV56543220, COSV56562588; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C2CD5 | c.987dup p.P330Afs*3 | Frame Shift Ins (INS) | VAF 77/377 reads (20%) | catalogued as rs754603484; called by mutect2, pindel, varscan2
- DDI1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56385497; called by muse, mutect2, varscan2
- DIDO1 | c.2573-2A>G p.X858_splice | Splice Site (SNP) | VAF 20/98 reads (20%) | catalogued as COSV56615466; called by mutect2, varscan2
- DOCK10 | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV51424676; called by muse, mutect2
- GBA3 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371096379; called by muse, mutect2
- IPP | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs762267700; called by muse, varscan2
- KCNV1 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV52086845; called by muse, mutect2, varscan2
- MUC5AC | c.15689C>T p.P5230L | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.649); catalogued as COSV100611382; called by muse, mutect2
- MUTYH | c.988+1G>C p.X330_splice | Splice Site (SNP) | VAF 151/491 reads (31%) | catalogued as COSV100588265; called by muse, mutect2, varscan2
- MYCBP2 | c.10124A>G p.N3375S (on ENST00000357337; = p.N3413S on NM_015057.5) | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs142620503; called by muse, mutect2, varscan2
- PCDHA2 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 23/671 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782204600, COSV65364884; called by muse, mutect2
- PDE5A | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV99308707; called by muse, mutect2, varscan2
- PEX5 | c.1768C>T p.R590W (on ENST00000420616; = p.R582W on NM_000319.5) | Missense Mutation (SNP) | VAF 32/541 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs139347001; called by muse, mutect2
- PRAM1 | c.1776G>A p.M592I | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1412647833; called by muse, mutect2
- PRKAA2 | c.1469G>T p.C490F | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as rs199623319; called by muse, mutect2, varscan2
- RYR2 | c.4754G>A p.R1585H | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1392451418, COSV63661428; called by muse, mutect2
- SACS | c.6814G>A p.G2272S | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV101207116, COSV66546750; called by muse, mutect2, varscan2
- SLC4A3 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.108); catalogued as rs1427737800; called by muse, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as rs759883814, COSV56092392; called by pindel, varscan2
- TMEM121B | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 182/652 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs1341585068; called by muse, mutect2, varscan2
- VEGFC | c.527C>A p.T176N | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1182586247, COSV54607715; called by muse, mutect2
- AC245033.1 | c.1550G>T p.G517V | Missense Mutation (SNP) | VAF 183/756 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ACSBG2 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ARFGEF3 | c.5297A>G p.N1766S | Missense Mutation (SNP) | VAF 55/291 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARHGEF10L | c.2273-1G>T p.X758_splice | Splice Site (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- ARNT | c.1523C>T p.T508I | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2
- ATP11A | c.1954G>C p.D652H | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- BAZ1A | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CATSPERD | c.650A>C p.Q217P | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CCDC34 | c.590A>C p.Q197P | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- CCDC34 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 49/278 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, varscan2
- CEACAM4 | c.630C>G p.A210= | Splice Region (SNP) | VAF 20/99 reads (20%) | called by mutect2, varscan2
- CELF3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- CFAP97 | c.1448C>T p.T483I | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CILK1 | c.1144C>A p.P382T | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CKAP5 | c.5692_5699del p.S1898Nfs*24 (on ENST00000529230 / NM_001008938.4; = p.S1838Nfs*24 on NM_014756.3) | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by pindel, varscan2
- ENTHD1 | c.1614C>G p.F538L | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAS | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 74/427 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- FBXO28 | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLG1 | c.2098A>C p.I700L | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HAUS1 | c.437del p.N146Ifs*2 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2
- IRAK4 | c.420T>G p.N140K | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM5D | c.4180G>T p.E1394* | Nonsense Mutation (SNP) | VAF 212/380 reads (56%) | called by muse, mutect2, varscan2
- KL | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRIQ1 | c.3862G>A p.G1288R | Missense Mutation (SNP) | VAF 119/524 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LTK | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- LYG2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MBD4 | c.636G>T p.L212F | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2
- MUC22 | c.3393A>G p.I1131M | Missense Mutation (SNP) | VAF 21/681 reads (3%) | SIFT tolerated (0.16); called by muse, mutect2
- NEBL | c.1412T>C p.M471T | Missense Mutation (SNP) | VAF 134/610 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NLRP1 | c.2528G>C p.R843P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, varscan2
- NOD1 | c.289T>A p.Y97N | Missense Mutation (SNP) | VAF 102/391 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NPAS3 | c.565C>G p.L189V (on ENST00000356141 / NM_001164749.2; = p.L157V on NM_022123.3) | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- NUMB | c.1000A>G p.I334V (on ENST00000355058; = p.I323V on NM_003744.5) | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR6C74 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2
- PBRM1 | c.3448C>T p.Q1150* (on ENST00000296302 / NM_001366071.2; = p.Q1125* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 111/329 reads (34%) | called by muse, mutect2, varscan2
- PHF19 | c.348_349del p.C116Wfs*20 | Frame Shift Del (DEL) | VAF 28/118 reads (24%) | called by mutect2, pindel, varscan2
- POGLUT1 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- PPP3CA | c.682T>G p.C228G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB2A | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RASAL1 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 83/306 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- RMDN1 | c.798del p.G267Efs*5 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | called by mutect2, pindel, varscan2
- SEC24A | c.629A>G p.H210R | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A9 | c.667_668insTAAAC p.E223Vfs*5 | Frame Shift Ins (INS) | VAF 40/232 reads (17%) | called by muse*, mutect2, varscan2*
- SLC2A4RG | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNAPC4 | c.1679T>A p.L560Q | Missense Mutation (SNP) | VAF 120/477 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.043); called by muse, varscan2
- SP140 | c.1570A>G p.S524G | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- SPTAN1 | c.642del p.K214Nfs*12 | Frame Shift Del (DEL) | VAF 43/212 reads (20%) | called by mutect2, pindel, varscan2
- SRRM2 | c.8047G>T p.D2683Y | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSTR4 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM39A | c.1264A>T p.N422Y | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOGARAM2 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 111/478 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- TRAPPC9 | c.1699A>T p.T567S | Missense Mutation (SNP) | VAF 54/646 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.111); called by muse, mutect2
- TRUB1 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- TUBA4B | c.517A>C p.I173L | Missense Mutation (SNP) | VAF 65/500 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- UBA1 | c.2221T>C p.F741L | Missense Mutation (SNP) | VAF 181/319 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- UBN1 | c.535T>A p.F179I | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- UROC1 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ZNF236 | c.458A>T p.H153L | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- CCDC59 | c.333C>T p.V111= | Silent (SNP) | VAF 71/313 reads (23%) | catalogued as rs998476954; called by muse, mutect2, varscan2
- CCDC93 | c.99C>G p.L33= | Silent (SNP) | VAF 53/227 reads (23%) | called by muse, mutect2, varscan2
- CHCHD3 | c.681A>C p.G227= | Silent (SNP) | VAF 69/265 reads (26%) | called by muse, mutect2, varscan2
- CLEC10A | c.207G>T p.L69= | Silent (SNP) | VAF 28/292 reads (10%) | called by muse, mutect2
- FGF14 | c.15C>A p.I5= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs772003315; called by muse, mutect2, varscan2
- IGKV1D-16 | c.147G>A p.Q49= | Silent (SNP) | VAF 90/1012 reads (9%) | catalogued as rs548097797; called by muse, mutect2
- KIT | c.459G>A p.G153= | Silent (SNP) | VAF 44/352 reads (13%) | called by muse, mutect2, varscan2
- LIG4 | c.273G>A p.K91= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- MACF1 | c.9945C>T p.C3315= | Silent (SNP) | VAF 53/217 reads (24%) | catalogued as rs769279319; called by muse, mutect2, varscan2
- MYOCD | c.1974T>G p.P658= | Silent (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- ODF2 | c.1828C>T p.L610= (on ENST00000434106 / NM_153433.2; = p.L586= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 96/507 reads (19%) | catalogued as rs533246171, COSV63548670; called by muse, mutect2, varscan2
- OR8B3 | c.388T>C p.L130= | Silent (SNP) | VAF 61/234 reads (26%) | catalogued as rs758875017; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2937A>G p.G979= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- S100A5 | c.186C>T p.N62= | Silent (SNP) | VAF 43/235 reads (18%) | called by muse, mutect2, varscan2
- SERINC1 | c.903C>T p.S301= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- SLC16A11 | c.750C>T p.G250= (on ENST00000308009; = p.G226= on NM_153357.3) | Silent (SNP) | VAF 91/345 reads (26%) | called by muse, mutect2, varscan2
- SLC41A1 | c.420T>G p.P140= | Silent (SNP) | VAF 158/492 reads (32%) | called by muse, mutect2, varscan2
- UNC5B | c.483C>G p.G161= | Silent (SNP) | VAF 64/350 reads (18%) | called by muse, mutect2, varscan2
- VANGL2 | c.678T>G p.L226= | Silent (SNP) | VAF 58/275 reads (21%) | called by muse, mutect2, varscan2
- ZFC3H1 | c.4071T>C p.N1357= | Silent (SNP) | VAF 43/212 reads (20%) | called by muse, mutect2, varscan2
- ANXA4 | c.398-10C>G | Intron (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- CGREF1 | c.-11-21T>C | Intron (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2882G>T | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- ECPAS | c.-220G>A | 5'UTR (SNP) | VAF 28/217 reads (13%) | catalogued as rs1244092883; called by muse, mutect2, varscan2
- FBRS | chr16:30659930 A>G | 5'Flank (SNP) | VAF 66/315 reads (21%) | called by muse, varscan2
- KCNIP2 | c.*4C>A | 3'UTR (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- KCTD15 | c.*379G>C | 3'UTR (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- LDHA | c.*554C>A | 3'UTR (SNP) | VAF 52/268 reads (19%) | called by muse, mutect2, varscan2
- MYRFL | c.-161del | 5'UTR (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- PRRT1 | c.*152C>A | 3'UTR (SNP) | VAF 14/353 reads (4%) | called by muse, mutect2
- SLC25A5 | c.-33C>T | 5'UTR (SNP) | VAF 205/396 reads (52%) | catalogued as rs748470956; called by muse, mutect2, varscan2
- WT1 | chr11:32439268 C>T | 5'Flank (SNP) | VAF 78/278 reads (28%) | called by muse, mutect2, varscan2
- YIF1B | c.*1099_*1104delinsT | 3'UTR (DEL) | VAF 76/379 reads (20%) | called by pindel, varscan2*
